Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6478, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6478-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONSIL, RIGHT, BIOPSY: INVASIVE POORLY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Direct laryngoscopy with biopsy

Operative Findings: Unspecified

Operative Diagnosis: Right oropharyngeal lesion

Tissue Submitted: 1) right tonsil

GROSS DESCRIPTION:

1) SOURCE: Right Tonsil

Submitted in saline in a container labeled with the patient's name, medical record number and "right tonsil" is a 0.7 x 0.7 x 0.6 cm piece of white, light-tan tissue with a small area of bright red. The entire surface is inked blue. The tissue is soft. The specimen is entirely submitted in cassette 1A, 3/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

[REDACTED] Release of Information [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 586bdf3c-4339-44c7-a0f2-3b2e62d5551c (TCGA-CR-6478.3EC65B65-8BD9-486F-8866-3DE22EFF8865.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).